Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3Y4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3Y4-01A (Primary Tumor).

Procurement Date: Laterality: Tumor Features: -1, Tumor Extent: Lesion less than 4.0cm,
Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Simple hysterectomy

Tumor site: Endocervix

Tumor size: 1.5 x 2 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 0/12 positive for metastasis (Pelvic fatty tissue 0/12)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
carcinoma, squamous cell, NOS
8070/3

Site: cervix, NOS
C53.9 6/6/12
RD

Reviewed (Initials):	Date Reviewed: 5/24/12	

5/24/12

Source: NCI Genomic Data Commons file e30ace24-717d-4bd8-9d9a-f40634db429d (TCGA-EA-A3Y4.D0A5BC9D-D39C-4A0D-9832-E062AA024D17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).